TCGA case TCGA-DD-A4NE — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bce25281-502e-4599-9679-32dc8462ffb1

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Dead; Days to death: 660 days (1.8 years).

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 75.4 years (27,549 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 660 days (1.8 years); Child pugh classification: A; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sorafenib; Days to treatment start: 225 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 75.9 years (27,739 days); Days to diagnosis: 190 days; Prior treatment: Yes.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 190 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Liver; Days to recurrence: 190 days.
- Day 190 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 190 days.
- Days to follow up: 660 days (1.8 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Platelets 348 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Creatinine 0.8 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1].
- Total Bilirubin 0.9 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Albumin 4.2 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Prothrombin Time 10.2 Seconds [Blood test normal range lower: 8.3; Blood test normal range upper: 10.8].
- Alpha Fetoprotein 28 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79 kg; Height: 170 cm; BMI: 27.3.
- Timepoint category: Prior to Diagnosis; Viral hepatitis serology tests: Hepatitis C Virus RNA / Hepatitis B Surface Antigen / HBV Core Antibody.

Family history
- Relatives with cancer history count: 3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-A4NE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 200 mg.
  Slide TCGA-DD-A4NE-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DD-A4NE-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-A4NE-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-DD-A4NE-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Extended Lobectomy.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis C Virus RNA; Viral hepatitis serology: Hepatitis B Surface Antigen; Viral hepatitis serology: HBV Core Antibody.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 660 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 660 days; disease-free interval: event (new tumor event after initially disease-free), 190 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 190 days.
